Somatic mutation profile of tumor specimen TCGA-56-6546-01A (aliquot TCGA-56-6546-01A-11D-1817-08) from TCGA case TCGA-56-6546, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 67.3 years (24,594 days).
Specimen TCGA-56-6546-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46019eeb-910f-4a58-b261-575e2a79ae28.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-6546-10A (Blood Derived Normal), aliquot TCGA-56-6546-10A-01D-1817-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b17c34a-0493-4512-ba56-79d2a5ca51c1

The open-access MAF lists 374 somatic variants for this specimen: 285 protein-altering or splice-affecting, 79 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 242, Silent 79, Nonsense Mutation 17, Frame Shift Del 13, Splice Site 5, RNA 4, Frame Shift Ins 3, 3'UTR 3, Splice Region 3, In Frame Del 2, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKR1D1 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as rs267606650, CM044568, COSV54338727; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 25/70 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AASDH | c.2916G>C p.Q972H | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as COSV52711056; called by muse, mutect2
- ABCA4 | c.1484C>A p.A495D | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs752765416, COSV64678671; called by muse, mutect2, varscan2
- ACAD8 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.846); catalogued as COSV55538919, COSV55542947; called by muse, mutect2, varscan2
- ADAMTSL1 | c.5090C>T p.A1697V | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV65886106; called by muse, mutect2, varscan2
- ADGRA2 | c.2455T>C p.S819P | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.825); catalogued as rs767322373, COSV55105763; called by muse, mutect2, varscan2
- ADGRL4 | c.349T>A p.L117I | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV66066460; called by muse, mutect2, varscan2
- ADRA2B | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.067); catalogued as rs759607097, COSV101337349, COSV69787367; called by muse, mutect2, varscan2
- AGXT2 | c.16A>T p.R6* | Nonsense Mutation (SNP) | VAF 12/66 reads (18%) | catalogued as COSV51491226, COSV99183697; called by muse, mutect2, varscan2
- AHNAK | c.3888T>A p.D1296E | Missense Mutation (SNP) | VAF 51/311 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.071); catalogued as COSV57232480; called by muse, mutect2, varscan2
- AKAP12 | c.2629G>A p.A877T | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV53582888; called by muse, mutect2, varscan2
- AP5M1 | c.782C>G p.S261C | Missense Mutation (SNP) | VAF 45/319 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV55107101; called by muse, mutect2, varscan2
- ARF5 | c.515G>T p.W172L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.473); catalogued as COSV50002157; called by muse, mutect2, varscan2
- ARFGEF3 | c.6404T>G p.F2135C | Missense Mutation (SNP) | VAF 42/214 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52471950; called by muse, mutect2, varscan2
- ARHGEF10L | c.1552A>T p.K518* | Nonsense Mutation (SNP) | VAF 5/34 reads (15%) | catalogued as COSV51441480; called by muse, mutect2, varscan2
- ARID2 | c.2101A>T p.T701S | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT tolerated, low confidence (0.51); PolyPhen probably damaging (0.97); catalogued as COSV57615627; called by muse, mutect2, varscan2
- ARMC6 | c.376G>T p.A126S (on ENST00000392336; = p.A101S on NM_033415.4) | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.327); catalogued as COSV54184568; called by muse, mutect2, varscan2
- ARMH4 | c.61G>T p.V21F | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50775589; called by muse, mutect2, varscan2
- ATP10A | c.2878C>A p.P960T | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV63525376; called by muse, mutect2, varscan2
- B3GAT2 | c.595C>G p.R199G | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100017508, COSV57769997, COSV57775208; called by muse, mutect2, varscan2
- BARD1 | c.1032T>G p.S344R | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV53618068; called by muse, mutect2, varscan2
- BPIFB4 | c.437G>T p.R146M | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV64952511; called by muse, mutect2, varscan2
- C14orf177 | n.616G>C | Splice Region (SNP) | VAF 7/40 reads (18%) | catalogued as COSV57901898; called by muse, mutect2, varscan2
- C2orf16 | c.3162T>A p.S1054R | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.038); catalogued as COSV62678610; called by muse, mutect2, varscan2
- C8B | c.1653G>T p.W551C | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64778282, COSV64779855; called by muse, mutect2, varscan2
- CACNA1C | c.6613T>G p.Y2205D (on ENST00000399634 / NM_001167625.1; = p.Y2134D on NM_000719.7) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as COSV59777051; called by muse, mutect2, varscan2
- CBLN2 | c.562G>T p.V188L | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV54053231; called by muse, mutect2, varscan2
- CCDC15 | c.1075G>T p.D359Y | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV61085135; called by muse, mutect2, varscan2
- CCDC183 | c.189G>C p.K63N | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV62012565, COSV62013632; called by muse, mutect2, varscan2
- CCDC191 | c.2038A>T p.K680* | Nonsense Mutation (SNP) | VAF 11/81 reads (14%) | catalogued as COSV55676779; called by muse, mutect2, varscan2
- CCT8L2 | c.751G>T p.A251S | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as COSV100742789, COSV63463927; called by muse, mutect2, varscan2
- CD163 | c.3262G>T p.E1088* | Nonsense Mutation (SNP) | VAF 28/158 reads (18%) | catalogued as COSV63131968, COSV63137796; called by muse, mutect2, varscan2
- CD163L1 | c.2540G>T p.G847V | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58010794, COSV58025502; called by muse, mutect2, varscan2
- CD33 | c.362A>G p.E121G | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV51799717; called by muse, mutect2, varscan2
- CD93 | c.1384C>A p.P462T | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.454); catalogued as COSV99848987; called by muse, mutect2, varscan2
- CDH16 | c.2134G>T p.V712L | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.987); catalogued as COSV55340052; called by muse, mutect2, varscan2
- CEACAM4 | c.112A>G p.I38V | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.333); catalogued as COSV55733320; called by muse, mutect2, varscan2
- CERKL | c.848G>A p.R283Q (on ENST00000339098 / NM_001030311.2; = p.R257Q on NM_201548.5) | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs762961333, COSV59203100; called by muse, mutect2, varscan2
- CFAP69 | c.1559G>T p.S520I | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.206); catalogued as COSV60188759; called by muse, mutect2, varscan2
- CHAT | c.1967C>A p.S656Y | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1387846647, COSV60333889; called by muse, mutect2, varscan2
- CHD5 | c.3031A>G p.N1011D | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.225); catalogued as COSV52426085; called by muse, mutect2, varscan2
- CHIA | c.346C>A p.R116S (on ENST00000343320; = p.R8S on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/217 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100588594; called by muse, mutect2, varscan2
- CNTNAP2 | c.1315C>A p.Q439K | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0.021); catalogued as COSV100664598, COSV62264864; called by muse, mutect2, varscan2
- COG4 | c.1282G>T p.E428* | Nonsense Mutation (SNP) | VAF 25/222 reads (11%) | catalogued as COSV60425407; called by muse, mutect2, varscan2
- COG4 | c.1281G>T p.M427I | Missense Mutation (SNP) | VAF 24/219 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV60425413; called by muse, mutect2, varscan2
- COL3A1 | c.2789G>A p.G930E | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM113075, COSV58597277; called by muse, mutect2, varscan2
- CORIN | c.2946+1G>C p.X982_splice | Splice Site (SNP) | VAF 12/104 reads (12%) | catalogued as rs532698694, COSV56700250; called by muse, mutect2, varscan2
- COX16 | c.47T>A p.L16H | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV66303434; called by muse, mutect2, varscan2
- CRHR2 | c.1053G>C p.Q351H | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59268123; called by muse, mutect2, varscan2
- CST1 | c.360C>G p.F120L | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59056472; called by muse, mutect2, varscan2
- CTSL | c.640A>T p.N214Y | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV58247660; called by muse, mutect2, varscan2
- DACH2 | c.527G>A p.S176N | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.186); catalogued as COSV64187343; called by mutect2, varscan2
- DCAF4 | c.143A>G p.D48G | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV62320646; called by muse, mutect2, varscan2
- DLGAP3 | c.2348C>T p.P783L | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.75); PolyPhen benign (0.19); catalogued as COSV52398373; called by muse, mutect2, varscan2
- DPP6 | c.401A>G p.E134G (on ENST00000377770 / NM_001364500.2; = p.E72G on NM_001936.5) | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV59647755; called by muse, mutect2, varscan2
- DSG4 | c.1291C>T p.H431Y | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV57398215; called by muse, mutect2, varscan2
- DSP | c.5512C>T p.R1838C | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs756481791, COSV65792256; called by muse, mutect2, varscan2
- DUS2 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs763439543, COSV62707902; called by muse, mutect2, varscan2
- DYNC1I1 | c.770G>T p.G257V | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV61461796, COSV61466844; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1317C>A p.D439E | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV62571179; called by muse, mutect2, varscan2
- EML2 | c.412C>T p.H138Y | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as COSV55604577; called by muse, mutect2, varscan2
- ENAM | c.3053A>T p.Q1018L | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV68537104; called by muse, mutect2, varscan2
- EPHA10 | c.638C>A p.A213D | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV57627549; called by muse, mutect2, varscan2
- ERBB3 | c.1868G>A p.G623E | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57264496; called by muse, mutect2, varscan2
- FAM110C | c.372G>C p.K124N | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV59656603; called by muse, varscan2
- FARP1 | c.2555A>G p.Q852R | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.815); catalogued as rs1296305759, COSV60349240; called by muse, mutect2, varscan2
- FAT4 | c.2180G>A p.S727N | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.477); catalogued as COSV67901448; called by muse, mutect2, varscan2
- FER1L6 | c.2953A>G p.I985V | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); catalogued as COSV67553009; called by muse, mutect2, varscan2
- FLT1 | c.850C>A p.Q284K | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV56744298; called by muse, mutect2, varscan2
- FYB1 | c.698C>A p.S233Y | Missense Mutation (SNP) | VAF 44/255 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as rs1435098886, COSV60957065; called by muse, mutect2, varscan2
- GABRG3 | c.380G>C p.W127S | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61521945, COSV61535125; called by muse, mutect2, varscan2
- GALNTL5 | c.944G>C p.R315P | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV67179970, COSV67181334; called by muse, mutect2, varscan2
- GCNA | c.653A>G p.K218R | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs138572604, COSV65466217; called by muse, varscan2
- GCNA | c.654G>C p.K218N | Missense Mutation (SNP) | VAF 44/221 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs141229655, COSV65466672; called by muse, varscan2
- GCSAM | c.219+2T>A p.X73_splice | Splice Site (SNP) | VAF 22/110 reads (20%) | catalogued as COSV58264654; called by muse, mutect2, varscan2
- GDA | c.607-2A>T p.X203_splice | Splice Site (SNP) | VAF 44/152 reads (29%) | catalogued as COSV52998071; called by muse, mutect2
- GLRB | c.550C>A p.P184T | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52423003; called by muse, mutect2, varscan2
- GML | c.341G>T p.G114V | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55278745; called by muse, mutect2, varscan2
- GOLGB1 | c.4771G>A p.E1591K | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1234145409, COSV61471711, COSV61472250; called by muse, mutect2, varscan2
- GP6 | c.702C>G p.F234L | Missense Mutation (SNP) | VAF 65/212 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV59979937; called by muse, mutect2, varscan2
- GRID1 | c.2449G>T p.A817S | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV60056001; called by muse, mutect2, varscan2
- GRIK4 | c.1826C>G p.S609C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV70807658; called by muse, varscan2
- GRK3 | c.1984C>G p.P662A | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV60800790; called by muse, mutect2, varscan2
- GTPBP4 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1352734265, COSV62552353; called by muse, mutect2, varscan2
- H3C12 | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV100377512; called by muse, mutect2, varscan2
- HCN1 | c.1909G>T p.A637S | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV57501369, COSV57539260; called by muse, mutect2
- HCN3 | c.1433G>T p.R478L | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as COSV61362653; called by muse, varscan2
- HEMGN | c.1016C>A p.S339Y | Missense Mutation (SNP) | VAF 61/227 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as COSV52328410; called by muse, mutect2, varscan2
- HIPK1 | c.108G>T p.Q36H | Missense Mutation (SNP) | VAF 60/405 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.188); catalogued as COSV65786905; called by muse, mutect2, varscan2
- HMCN1 | c.3598C>A p.P1200T | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54945029; called by muse, mutect2, varscan2
- HRH3 | c.1094G>A p.S365N | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV58050664; called by muse, mutect2, varscan2
- HS3ST5 | c.55C>A p.L19I | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV57152918; called by muse, mutect2, varscan2
- HSPG2 | c.11252C>A p.P3751Q | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65934118; called by muse, mutect2, varscan2
- IGSF3 | c.159G>C p.Q53H | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59599182; called by muse, mutect2, varscan2
- IL18RAP | c.168C>A p.F56L | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV51829582; called by muse, mutect2, varscan2
- INPP4A | c.1988C>A p.T663N (on ENST00000074304 / NM_001134224.1; = p.T624N on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50840490; called by muse, varscan2
- ITGA10 | c.936G>T p.Q312H | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV65199368; called by muse, mutect2, varscan2
- ITIH6 | c.2845G>T p.G949C | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as COSV54495165; called by muse, mutect2, varscan2
- ITPRID2 | c.1844G>A p.G615E | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as rs141978094; called by muse, mutect2, varscan2
- ITPRID2 | c.2362A>C p.M788L | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV57476890; called by muse, mutect2, varscan2
- KATNAL2 | c.305C>T p.P102L (on ENST00000356157 / NM_001353899.1; = p.P30L on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/296 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs181204080, COSV55296487; called by muse, mutect2, varscan2
- KCNJ12 | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.45); catalogued as COSV59164166; called by muse, mutect2
- KHDRBS2 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1432676329, COSV55494830; called by muse, mutect2, varscan2
- KIF13B | c.2335G>T p.V779L | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV72879548; called by muse, mutect2, varscan2
- KLRF1 | c.212A>G p.Q71R | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV54382249; called by muse, mutect2, varscan2
- KRT33B | c.66_67insA p.P23Tfs*89 | Frame Shift Ins (INS) | VAF 11/56 reads (20%) | catalogued as COSV99290508, COSV99290845; called by mutect2, pindel, varscan2
- LCN6 | c.8G>A p.G3D | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as rs766019651, COSV57911820; called by muse, mutect2, varscan2
- LILRB3 | c.1499C>A p.A500D (on ENST00000346401; = p.A488D on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV54437727, COSV54447750; called by muse, mutect2, varscan2
- LIN54 | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs1170580981, COSV61203056; called by muse, mutect2, varscan2
- LIPE | c.2149G>C p.E717Q | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.688); catalogued as COSV54925862; called by muse, mutect2, varscan2
- LMTK2 | c.3253A>C p.T1085P | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV52004822; called by muse, mutect2, varscan2
- LPA | c.2650C>G p.P884A | Missense Mutation (SNP) | VAF 46/286 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1455844000, COSV60301472, COSV60313538; called by muse, mutect2, varscan2
- LRP1B | c.8022C>G p.C2674W | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67279070; called by muse, mutect2, varscan2
- LRP1B | c.2662G>C p.D888H | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.5); catalogued as COSV63341658, COSV63342038; called by muse, mutect2, varscan2
- LRP2 | c.2149G>C p.V717L | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55576641; called by muse, mutect2
- LRRCC1 | c.1907A>G p.Y636C | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64486084; called by muse, mutect2, varscan2
- LRRK2 | c.2504T>C p.I835T | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs1359938859, COSV54172686; called by muse, mutect2, varscan2
- MAEL | c.1217A>G p.N406S | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV63306488; called by muse, mutect2, varscan2
- MAGEC3 | c.77G>A p.C26Y | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as COSV53577096, COSV74217477; called by muse, mutect2, varscan2
- MASP2 | c.1759T>A p.Y587N | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.611); catalogued as COSV53571436; called by muse, mutect2, varscan2
- MATK | c.1357G>C p.V453L (on ENST00000310132 / NM_139355.3; = p.V454L on NM_002378.4) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV100035761, COSV59553131, COSV59556917; called by muse, mutect2, varscan2
- MEFV | c.2018C>A p.S673Y | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54828058; called by muse, mutect2, varscan2
- MMP16 | c.1070T>C p.M357T | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54191489; called by muse, mutect2, varscan2
- MRC2 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1419305567, COSV57645025; called by muse, varscan2
- MRGPRX4 | c.376T>A p.W126R | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as COSV58591837; called by muse, mutect2, varscan2
- MROH2B | c.2401C>A p.P801T | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68189974; called by muse, mutect2, varscan2
- MRPL19 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.556); catalogued as rs370208064; called by muse, mutect2, varscan2
- MUC16 | c.21818G>C p.G7273A | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as COSV67496836; called by muse, mutect2, varscan2
- MUC3A | c.511A>T p.T171S | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious, low confidence (0.05); catalogued as COSV100114159; called by muse, mutect2, varscan2
- MUC5B | c.3777C>A p.C1259* | Nonsense Mutation (SNP) | VAF 3/25 reads (12%) | catalogued as COSV71595852; called by muse, mutect2
- MYBPC3 | c.1139A>T p.K380M | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57034300; called by muse, mutect2, varscan2
- MYH2 | c.4374C>A p.I1458= | Splice Region (SNP) | VAF 21/60 reads (35%) | catalogued as COSV55449541; called by muse, mutect2, varscan2
- MYH2 | c.2070G>T p.M690I | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV55449554; called by muse, mutect2, varscan2
- MYH2 | c.2069T>A p.M690K | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV55449564; called by muse, mutect2, varscan2
- MYO18B | c.7039C>A p.Q2347K | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs572116317, COSV100122867; called by muse, mutect2, varscan2
- MYOM2 | c.1920C>A p.D640E | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs149434055; called by muse, mutect2
- NADSYN1 | c.1802A>G p.Y601C | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs753850438, COSV59815393; called by muse, mutect2, varscan2
- NAV3 | c.2502T>A p.D834E | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV57114641; called by muse, mutect2, varscan2
- NAV3 | c.6015C>A p.Y2005* (on ENST00000397909 / NM_001024383.2; = p.Y1983* on NM_014903.6) | Nonsense Mutation (SNP) | VAF 22/133 reads (17%) | catalogued as COSV57114648; called by muse, mutect2, varscan2
- NBAS | c.7110G>T p.W2370C | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55739093; called by muse, mutect2, varscan2
- NCAPG2 | c.1446G>T p.M482I | Missense Mutation (SNP) | VAF 53/277 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV51992062; called by muse, mutect2, varscan2
- NDN | c.610G>T p.G204C | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.264); catalogued as rs772773476, COSV100086306, COSV100086746; called by muse, mutect2, varscan2
- NDST4 | c.2575C>A p.P859T | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.066); catalogued as rs745606272, COSV52139004; called by muse, mutect2, varscan2
- NDST4 | c.633G>C p.E211D | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as COSV52139019; called by muse, mutect2
- NFATC2 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.992); catalogued as rs1236071141, COSV65361589; called by muse, mutect2, varscan2
- NKX2-2 | c.641C>A p.P214Q | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65820436; called by muse, mutect2, varscan2
- NLRC4 | c.454C>A p.L152M | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.059); catalogued as COSV61595042; called by muse, mutect2, varscan2
- NLRP12 | c.1831T>A p.L611M | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60756164; called by muse, mutect2, varscan2
- NLRP13 | c.739C>T p.Q247* | Nonsense Mutation (SNP) | VAF 42/194 reads (22%) | catalogued as rs780479553, COSV61622673; called by muse, varscan2
- NT5DC3 | c.1424A>G p.Q475R | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.082); catalogued as COSV67323077; called by muse, mutect2, varscan2
- NUP210 | c.3358G>T p.A1120S | Missense Mutation (SNP) | VAF 72/200 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV54414745; called by muse, mutect2, varscan2
- NUP210L | c.2673T>A p.D891E | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV55158674; called by muse, mutect2, varscan2
- OR11H12 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV73543902; called by muse, mutect2, varscan2
- OR2B11 | c.613G>C p.V205L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as COSV59511691; called by muse, mutect2, varscan2
- OR2C3 | c.268C>A p.Q90K | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as rs777675882, COSV63576489; called by muse, mutect2, varscan2
- OR2W3 | c.791C>A p.A264D | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV64457186; called by muse, mutect2, varscan2
- OR4C12 | c.466A>G p.I156V | Missense Mutation (SNP) | VAF 38/213 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.12); catalogued as COSV58861213; called by muse, mutect2, varscan2
- OR4K5 | c.965T>A p.F322Y | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.012); catalogued as COSV60005401; called by muse, mutect2, varscan2
- OR4X2 | c.478T>C p.F160L | Missense Mutation (SNP) | VAF 36/322 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as COSV56585328; called by muse, mutect2, varscan2
- OR51L1 | c.416C>G p.T139S | Missense Mutation (SNP) | VAF 42/227 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV58625906; called by muse, mutect2, varscan2
- OR5AP2 | c.158T>A p.V53E | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.148); catalogued as COSV57259222; called by muse, mutect2, varscan2
- OR5M10 | c.436A>G p.T146A | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as COSV73242462; called by muse, mutect2, varscan2
- P2RY10 | c.151G>T p.A51S | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.159); catalogued as COSV50687232; called by muse, mutect2, varscan2
- PAPPA2 | c.1066C>A p.H356N | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.223); catalogued as COSV62787554; called by muse, mutect2, varscan2
- PCDHB12 | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 24/102 reads (24%) | catalogued as COSV53401437; called by muse, mutect2, varscan2
- PCDHB4 | c.482T>A p.V161E | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.875); catalogued as COSV52027469; called by muse, mutect2, varscan2
- PCDHGA11 | c.1245G>T p.L415F | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV54042315; called by muse, mutect2, varscan2
- PCDHGB3 | c.2138T>C p.L713P | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54042290; called by muse, mutect2, varscan2
- PDYN | c.526G>T p.G176W | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54103575; called by muse, mutect2, varscan2
- PDZRN4 | c.2777C>G p.T926S (on ENST00000402685 / NM_001164595.2; = p.T668S on NM_013377.4) | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV54218492; called by muse, mutect2, varscan2
- PELI2 | c.568G>A p.V190I | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.989); catalogued as rs137897340; called by muse, mutect2, varscan2
- PHACTR3 | c.1443A>C p.R481S | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63034806; called by muse, mutect2
- PIK3R4 | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63244167; called by mutect2, varscan2
- PLEKHO2 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as rs200060372, COSV60263105; called by muse, mutect2, varscan2
- PMFBP1 | c.1937G>T p.R646L (on ENST00000537465; = p.R641L on NM_031293.3) | Missense Mutation (SNP) | VAF 29/303 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.363); catalogued as COSV52822054, COSV52825354; called by muse, mutect2, varscan2
- PMPCB | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50788208; called by muse, mutect2
- PMS1 | c.2027C>T p.P676L | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.764); catalogued as COSV59717389, COSV59720446; called by muse, mutect2, varscan2
- POPDC3 | c.68A>G p.Q23R | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV54646517; called by muse, mutect2, varscan2
- POU3F2 | c.1012T>A p.S338T | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV60409651; called by muse, mutect2, varscan2
- PPEF1 | c.685T>A p.L229M | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62996896; called by muse, mutect2, varscan2
- PPEF2 | c.1534T>A p.Y512N | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54426581; called by muse, mutect2, varscan2
- PRH1 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 27/233 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.373); catalogued as COSV70372314; called by muse, mutect2, varscan2
- PRSS12 | c.2323C>T p.R775* | Nonsense Mutation (SNP) | VAF 19/105 reads (18%) | catalogued as rs201069442, COSV56610836; called by muse, mutect2, varscan2
- PSG8 | c.1004C>A p.P335H | Missense Mutation (SNP) | VAF 52/218 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100126038; called by muse, mutect2, varscan2
- PTPRCAP | c.236G>T p.R79L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as COSV100396291; called by muse, mutect2
- PTTG2 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199864421; called by muse, mutect2, varscan2
- RAB3IP | c.1022A>T p.Y341F (on ENST00000550536 / NM_175623.4; = p.Y325F on NM_022456.5) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.97); catalogued as COSV56086960; called by muse, mutect2, varscan2
- RAD54L | c.1183A>G p.R395G | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64337082; called by muse, varscan2
- RBM14 | c.475G>C p.V159L | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV59557695, COSV59560956; called by muse, mutect2, varscan2
- RGS13 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV67346737; called by muse, mutect2
- RNF216 | c.737A>T p.Q246L (on ENST00000425013 / NM_207116.3; = p.Q303L on NM_207111.4) | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.1); catalogued as COSV66292869; called by muse, mutect2, varscan2
- ROBO3 | c.785G>T p.R262L | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV67302937, COSV67303150; called by muse, mutect2, varscan2
- RPS6KA3 | c.892C>T p.L298F | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.926); catalogued as COSV65389600; called by muse, mutect2, varscan2
- RREB1 | c.1550C>T p.T517M | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1413099895, COSV58566138; called by muse, mutect2, varscan2
- RSPH10B2 | c.579del p.I194Ffs*25 | Frame Shift Del (DEL) | VAF 11/69 reads (16%) | catalogued as COSV99786327; called by mutect2, pindel, varscan2
- RSPH14 | c.115G>T p.D39Y | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.744); catalogued as COSV53272566; called by muse, mutect2
- RUNX2 | c.1096G>T p.E366* (on ENST00000371438; = p.E344* on NM_001015051.3) | Nonsense Mutation (SNP) | VAF 26/136 reads (19%) | catalogued as CM106310, COSV61846309; called by muse, mutect2, varscan2
- RYR2 | c.3397C>A p.R1133S | Missense Mutation (SNP) | VAF 54/264 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.018); catalogued as COSV63717173; called by muse, mutect2, varscan2
- RYR3 | c.6210G>T p.M2070I | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV66809698; called by muse, mutect2, varscan2
- RYR3 | c.6735G>T p.Q2245H | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100774379; called by muse, mutect2, varscan2
- RYR3 | c.6736G>T p.G2246C | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV63109865; called by muse, mutect2, varscan2
- SCN9A | c.3677del p.L1226Rfs*18 (on ENST00000303354; = p.L1215Rfs*18 on NM_002977.3) | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | catalogued as COSV57627893; called by mutect2, pindel, varscan2
- SCN9A | c.649A>G p.R217G | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100311831; called by muse, mutect2, varscan2
- SEC23IP | c.2623A>C p.I875L | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT tolerated (0.74); PolyPhen benign (0.23); catalogued as COSV64833270; called by muse, mutect2, varscan2
- SGCD | c.67A>C p.K23Q (on ENST00000435422 / NM_001128209.2; = p.K24Q on NM_000337.5) | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.939); catalogued as COSV61917211; called by muse, mutect2, varscan2
- SLC12A5 | c.217-1G>A p.X73_splice (on ENST00000454036 / NM_001134771.2; = p.X50_splice on NM_020708.5) | Splice Site (SNP) | VAF 103/315 reads (33%) | catalogued as COSV54802717; called by muse, mutect2, varscan2
- SLC16A7 | c.436G>T p.A146S | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53894689, COSV53899998; called by muse, mutect2, varscan2
- SLC1A2 | c.1636A>T p.I546L | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV53526486; called by muse, mutect2, varscan2
- SLC25A25 | c.550G>T p.G184W | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100895265; called by muse, mutect2, varscan2
- SLC26A7 | c.1560T>A p.Y520* | Nonsense Mutation (SNP) | VAF 39/170 reads (23%) | catalogued as COSV52605503; called by muse, mutect2, varscan2
- SLC30A2 | c.85G>T p.G29C | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV65333447; called by muse, mutect2, varscan2
- SLC35A2 | c.556C>G p.Q186E | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.27); PolyPhen benign (0.055); catalogued as COSV54431935; called by muse, mutect2, varscan2
- SLC38A1 | c.1070G>T p.R357L | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV101284116; called by muse, mutect2, varscan2
- SLC38A8 | c.1028G>T p.G343V | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.91); catalogued as COSV55309867; called by muse, mutect2, varscan2
- SLC5A7 | c.448G>T p.G150* | Nonsense Mutation (SNP) | VAF 14/62 reads (23%) | catalogued as rs369645282; called by mutect2, varscan2
- SLC6A17 | c.403A>G p.I135V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.024); catalogued as rs753970226, COSV58997141; called by muse, mutect2, varscan2
- SLC6A2 | c.1736G>T p.S579I | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.127); catalogued as COSV54923972; called by muse, mutect2, varscan2
- SLC9A9 | c.623G>T p.G208V | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV57230342, COSV57246609; called by muse, varscan2
- SLC9A9 | c.622G>T p.G208C | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1242808400, COSV57246806; called by muse, mutect2, varscan2
- SLCO1B1 | c.1957G>T p.E653* | Nonsense Mutation (SNP) | VAF 5/48 reads (10%) | catalogued as COSV57017673; called by muse, mutect2, varscan2
- SLITRK2 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.95); PolyPhen benign (0.03); catalogued as COSV100158074, COSV59429078; called by muse, mutect2, varscan2
- SLX4 | c.3697G>T p.G1233W | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.932); catalogued as COSV99567739; called by muse, mutect2, varscan2
- SMARCA2 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs1448350538, COSV61813220; called by muse, mutect2
- SMPD4 | c.2317G>T p.G773C (on ENST00000409031 / NM_017951.4; = p.G744C on NM_017751.4) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100302252; called by muse, mutect2, varscan2
- SNRNP48 | c.972-1G>T p.X324_splice | Splice Site (SNP) | VAF 9/48 reads (19%) | catalogued as COSV100672903; called by muse, mutect2, varscan2
- SOX6 | c.2090C>T p.T697I (on ENST00000528429 / NM_001145819.2; = p.T670I on NM_017508.3) | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57053835; called by muse, mutect2
- STK36 | c.2119C>T p.H707Y | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs1326034474, COSV55331209; called by muse, mutect2, varscan2
- STON1 | c.1391C>G p.P464R | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV59138955; called by muse, mutect2, varscan2
- SYCE2 | c.82C>A p.P28T | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.052); catalogued as COSV53368755; called by muse, mutect2, varscan2
- SYNJ2 | c.2171G>T p.C724F | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1412269826, COSV62901123; called by muse, mutect2, varscan2
- SYT13 | c.1138G>T p.G380C | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.87); catalogued as COSV50077460; called by muse, mutect2, varscan2
- SYT9 | c.571C>A p.Q191K | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as COSV59625705; called by muse, mutect2, varscan2
- THNSL2 | c.233A>T p.D78V | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV59085047; called by muse, mutect2, varscan2
- TKTL2 | c.1092A>G p.I364M | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54921485; called by muse, mutect2, varscan2
- TNXB | c.6040G>A p.D2014N (on ENST00000647633; = p.D1767N on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.241); catalogued as COSV64489599; called by muse, mutect2
- TPR | c.6617C>T p.S2206L | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV66605383; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1837A>G p.S613G | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as COSV61459206; called by muse, mutect2, varscan2
- TRIM60 | c.908C>A p.T303K | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61971855; called by muse, mutect2
- TRIM72 | c.691G>C p.D231H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.862); catalogued as COSV57252359; called by muse, mutect2
- TROAP | c.1234C>A p.P412T | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs181203315, COSV57746140; called by muse, mutect2, varscan2
- TTN | c.97546T>A p.C32516S (on ENST00000591111; = p.C25092S on NM_003319.4) | Missense Mutation (SNP) | VAF 25/176 reads (14%) | PolyPhen probably damaging (0.996); catalogued as COSV60374482; called by muse, mutect2, varscan2
- TTN | c.59120del p.P19707Lfs*17 (on ENST00000591111; = p.P12283Lfs*17 on NM_003319.4) | Frame Shift Del (DEL) | VAF 60/378 reads (16%) | catalogued as COSV60238475; called by mutect2, pindel, varscan2
- TTN | c.26168G>C p.S8723T (on ENST00000591111; = p.S7796T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | PolyPhen benign (0.163); catalogued as COSV60374520; called by muse, mutect2, varscan2
- TTN | c.19127G>T p.G6376V (on ENST00000591111; = p.G5449V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/90 reads (14%) | PolyPhen probably damaging (1); catalogued as COSV60198638, COSV60374536; called by muse, mutect2, varscan2
- UFL1 | c.2380G>T p.E794* | Nonsense Mutation (SNP) | VAF 7/44 reads (16%) | catalogued as COSV65150782; called by muse, mutect2
- UGT1A8 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65086875; called by muse, mutect2, varscan2
- USF2 | c.515C>A p.A172E | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV55888430, COSV55888518; called by muse, mutect2, varscan2
- VANGL2 | c.148G>T p.G50W | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV99058431; called by muse, mutect2, varscan2
- VAPB | c.706G>T p.V236L | Missense Mutation (SNP) | VAF 78/386 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.192); catalogued as COSV55669624; called by muse, mutect2, varscan2
- VEZT | c.893G>A p.C298Y | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1186590384, COSV54145677; called by muse, mutect2, varscan2
- WDR17 | c.75G>A p.M25I | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV54585049; called by muse, mutect2
- XIRP2 | c.3628A>T p.S1210C (on ENST00000628543; = p.S1385C on NM_152381.6) | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV54737024; called by muse, mutect2, varscan2
- XPO6 | c.518G>T p.R173L | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.06); catalogued as COSV100484790; called by muse, mutect2, varscan2
- YIF1A | c.392G>T p.R131L | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV100268346, COSV100268600; called by muse, mutect2, varscan2
- ZC3HC1 | c.700A>T p.T234S | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.82); PolyPhen benign (0.005); catalogued as COSV61300462; called by muse, mutect2, varscan2
- ZFHX4 | c.3193C>A p.H1065N | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51440722, COSV51498649; called by muse, mutect2, varscan2
- ZNF208 | c.1868C>A p.T623N | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV101237168, COSV68113202; called by muse, varscan2
- ZNF467 | c.1004C>A p.S335Y | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as COSV57375020; called by muse, mutect2, varscan2
- ZNF536 | c.2579C>T p.T860I | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.05); catalogued as rs1297841406, COSV62835085; called by muse, mutect2, varscan2
- ZNF574 | c.661C>T p.Q221* | Nonsense Mutation (SNP) | VAF 36/141 reads (26%) | catalogued as COSV55907217; called by muse, mutect2, varscan2
- ZNF648 | c.659C>G p.A220G | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV60572949, COSV99046084; called by muse, mutect2
- ZNF676 | c.505G>C p.G169R (on ENST00000650058; = p.G137R on NM_001001411.3) | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.198); catalogued as COSV68095154; called by muse, mutect2, varscan2
- ZNF71 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.074); catalogued as rs773251975, COSV60150508; called by muse, mutect2, varscan2
- ZNF766 | c.590G>T p.R197I | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.054); catalogued as COSV63010370; called by muse, mutect2, varscan2
- AFAP1L1 | c.101_103del p.K34del | In Frame Del (DEL) | VAF 12/48 reads (25%) | called by pindel, varscan2
- BCHE | c.1458del p.A487Pfs*5 | Frame Shift Del (DEL) | VAF 16/109 reads (15%) | called by mutect2, pindel, varscan2
- DAGLA | c.1361_1364del p.G454Efs*12 | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | called by mutect2, pindel
- DNAAF1 | c.2047_2060del p.L683Sfs*5 | Frame Shift Del (DEL) | VAF 11/57 reads (19%) | called by mutect2, pindel, varscan2
- H4C8 | c.269_272del p.A90Gfs*? | Frame Shift Del (DEL) | VAF 16/111 reads (14%) | called by mutect2, pindel, varscan2
- HCN3 | c.577del p.E193Sfs*24 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | called by mutect2, pindel, varscan2
- HERC2 | c.1650del p.K551Sfs*47 | Frame Shift Del (DEL) | VAF 10/51 reads (20%) | called by mutect2, pindel, varscan2
- HPD | c.373del p.Q125Kfs*7 | Frame Shift Del (DEL) | VAF 35/229 reads (15%) | called by mutect2, pindel, varscan2
- LENG9 | c.558_561dup p.P188Cfs*38 | Frame Shift Ins (INS) | VAF 9/31 reads (29%) | called by mutect2, pindel, varscan2
- MUC5B | c.7123C>A p.Q2375K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- NPR3 | c.1608_1609del p.H537Ffs*40 (on ENST00000265074 / NM_001364458.2; = p.H536Ffs*? on NM_000908.4) | Frame Shift Del (DEL) | VAF 7/39 reads (18%) | called by mutect2, pindel, varscan2
- OR51L1 | c.220G>T p.G74W | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPIG | c.2042dup p.A682Gfs*2 | Frame Shift Ins (INS) | VAF 18/120 reads (15%) | called by mutect2, varscan2
- PRAMEF8 | c.1234C>A p.P412T | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTGS2 | c.565_573del p.Q189_F191del | In Frame Del (DEL) | VAF 15/124 reads (12%) | called by mutect2, pindel, varscan2
- RTF2 | c.846del p.F282Lfs*43 | Frame Shift Del (DEL) | VAF 39/159 reads (25%) | called by mutect2, pindel, varscan2
- SYNRG | c.1609G>T p.D537Y | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAV8-2 | c.148C>G p.P50A | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- TUBB7P | n.276C>A | Splice Region (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- UBTF | c.1781del p.K594Rfs*63 | Frame Shift Del (DEL) | VAF 11/64 reads (17%) | called by mutect2, pindel, varscan2
- ABTB1 | c.828C>T p.F276= (on ENST00000232744 / NM_172027.3; = p.F134= on NM_032548.3) | Silent (SNP) | VAF 35/154 reads (23%) | catalogued as COSV51743093; called by muse, mutect2, varscan2
- ALPG | c.507G>A p.R169= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as rs564544259, COSV54968406; called by muse, mutect2, varscan2
- ANKRD30A | c.996G>A p.V332= (on ENST00000611781; = p.V276= on NM_052997.2) | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as COSV64618866; called by muse, mutect2, varscan2
- APLP1 | c.1365G>T p.V455= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as COSV55707252; called by muse, mutect2, varscan2
- ASXL3 | c.252G>A p.E84= | Silent (SNP) | VAF 26/106 reads (25%) | catalogued as COSV52469165, COSV52480834; called by muse, mutect2, varscan2
- B3GNT8 | c.12C>T p.P4= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV54199984; called by muse, mutect2, varscan2
- BCL7C | c.594A>T p.T198= | Silent (SNP) | VAF 33/217 reads (15%) | catalogued as COSV53064630; called by muse, mutect2, varscan2
- BTBD17 | c.258G>A p.L86= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as rs1270310595, COSV64730836; called by muse, mutect2, varscan2
- CEP350 | c.1920T>C p.F640= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV62610268; called by muse, mutect2
- CHPF | c.2247C>T p.L749= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV60537004; called by muse, mutect2, varscan2
- CLEC14A | c.504C>T p.G168= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as rs1344566728, COSV60564492; called by muse, mutect2, varscan2
- CSMD2 | c.3438C>T p.S1146= | Silent (SNP) | VAF 34/162 reads (21%) | catalogued as rs749524000, COSV53964039; called by muse, mutect2, varscan2
- CSMD3 | c.3577C>A p.R1193= (on ENST00000297405 / NM_001363185.1; = p.R1089= on NM_052900.3) | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as COSV52145880, COSV52331660; called by muse, mutect2, varscan2
- CST1 | c.177C>A p.T59= | Silent (SNP) | VAF 28/161 reads (17%) | catalogued as rs773666920, COSV59056298; called by muse, mutect2, varscan2
- CYTH1 | c.753G>T p.G251= | Silent (SNP) | VAF 60/195 reads (31%) | catalogued as COSV63123832; called by muse, mutect2, varscan2
- DPY19L1 | c.2019A>T p.V673= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as COSV60584568; called by muse, mutect2, varscan2
- DSG1 | c.2277A>T p.A759= | Silent (SNP) | VAF 29/209 reads (14%) | catalogued as COSV57139679; called by muse, mutect2, varscan2
- DSP | c.8241C>A p.T2747= | Silent (SNP) | VAF 20/126 reads (16%) | catalogued as rs748231845, COSV100672902; called by muse, mutect2, varscan2
- EIF2S1 | c.93G>A p.G31= | Silent (SNP) | VAF 34/180 reads (19%) | catalogued as COSV53600777; called by muse, mutect2, varscan2
- GABBR2 | c.1827G>C p.L609= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV52320889; called by muse, mutect2, varscan2
- GAK | c.3219C>T p.S1073= | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as COSV58508449, COSV58510341; called by muse, mutect2, varscan2
- GJA10 | c.93C>T p.I31= | Silent (SNP) | VAF 29/139 reads (21%) | catalogued as COSV65356425; called by muse, mutect2, varscan2
- GPATCH4 | c.246A>T p.V82= | Silent (SNP) | VAF 45/342 reads (13%) | catalogued as COSV58041651; called by muse, mutect2, varscan2
- GRIK4 | c.124C>A p.R42= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as COSV70805104, COSV70807654; called by muse, mutect2, varscan2
- GRIN2B | c.3702G>A p.S1234= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as rs753797364, COSV101662902, COSV74205743, COSV74208198; called by muse, mutect2, varscan2
- H6PD | c.1875A>T p.P625= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs1370173709, COSV66232504; called by muse, mutect2, varscan2
- HMSD | c.336T>C p.T112= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV68817159; called by muse, mutect2, varscan2
- HOXC10 | c.672A>G p.K224= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV57727194; called by muse, mutect2, varscan2
- ICE1 | c.5223G>T p.V1741= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99664038; called by muse, mutect2, varscan2
- IL23R | c.1341T>C p.P447= | Silent (SNP) | VAF 20/183 reads (11%) | catalogued as rs747337602, COSV61375702; called by muse, mutect2, varscan2
- ITPKC | c.1422G>T p.L474= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV54577635; called by muse, mutect2, varscan2
- KCNIP3 | c.228A>G p.P76= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV54673489; called by muse, mutect2, varscan2
- KIF19 | c.1308G>T p.V436= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs1465651494, COSV63430718; called by muse, mutect2, varscan2
- KLHL18 | c.528C>T p.F176= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV51743976; called by muse, mutect2, varscan2
- LILRB5 | c.1122T>C p.Y374= | Silent (SNP) | VAF 23/105 reads (22%) | catalogued as rs778335452, COSV60260584, COSV60261403; called by muse, mutect2, varscan2
- LINGO1 | c.222C>G p.R74= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV62438744; called by muse, mutect2
- LRP12 | c.1344C>T p.C448= | Silent (SNP) | VAF 26/131 reads (20%) | catalogued as COSV52635099; called by muse, mutect2, varscan2
- LRP1B | c.1725C>T p.T575= | Silent (SNP) | VAF 36/180 reads (20%) | catalogued as rs1451059348, COSV67279075; called by muse, mutect2, varscan2
- LRRC7 | c.2148G>T p.L716= (on ENST00000651989 / NM_001370785.2; = p.L683= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as COSV50467751, COSV50641289; called by muse, mutect2, varscan2
- MDN1 | c.3252A>T p.G1084= | Silent (SNP) | VAF 58/363 reads (16%) | catalogued as rs748012979, COSV65531111; called by muse, mutect2, varscan2
- MIOS | c.387A>T p.L129= | Silent (SNP) | VAF 36/143 reads (25%) | catalogued as rs1253434445, COSV60770836; called by muse, mutect2, varscan2
- MROH5 | c.2394C>T p.T798= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV71303007; called by muse, mutect2, varscan2
- MUC5B | c.7122C>A p.G2374= | Silent (SNP) | VAF 8/26 reads (31%) | called by mutect2, varscan2
- MYH7 | c.3984C>G p.A1328= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV62524415; called by muse, mutect2, varscan2
- NLRP12 | c.1320G>T p.L440= | Silent (SNP) | VAF 30/182 reads (16%) | catalogued as COSV60756185; called by muse, mutect2, varscan2
- NLRP13 | c.2391T>A p.T797= | Silent (SNP) | VAF 67/212 reads (32%) | catalogued as rs537430301, COSV61624246; called by muse, mutect2, varscan2
- NUTM2A | c.405C>A p.G135= | Silent (SNP) | VAF 5/16 reads (31%) | called by mutect2, varscan2
- OR52B2 | c.499C>A p.R167= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV73209607, COSV73209660; called by muse, mutect2, varscan2
- OR52E8 | c.303A>T p.G101= | Silent (SNP) | VAF 40/239 reads (17%) | catalogued as COSV66213077; called by muse, varscan2
- OR8H3 | c.528C>T p.H176= | Silent (SNP) | VAF 22/200 reads (11%) | catalogued as COSV57911834; called by muse, mutect2
- P4HA2 | c.1473G>C p.R491= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV51332483; called by muse, mutect2, varscan2
- PDE3A | c.2955C>T p.P985= | Silent (SNP) | VAF 25/127 reads (20%) | catalogued as COSV62983586; called by muse, mutect2, varscan2
- PKHD1L1 | c.6333C>T p.V2111= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs1447235911, COSV65754322; called by muse, mutect2, varscan2
- PKP2 | c.1113T>C p.S371= | Silent (SNP) | VAF 29/139 reads (21%) | catalogued as COSV50750903; called by muse, mutect2, varscan2
- PLCL1 | c.2496G>T p.V832= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV101406823; called by muse, mutect2, varscan2
- PTBP2 | c.1176T>C p.D392= (on ENST00000426398 / NM_001300986.2; = p.D384= on NM_021190.4) | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as rs769574433, COSV64626669; called by muse, mutect2, varscan2
- PTPRD | c.5538G>A p.A1846= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as rs755813376, COSV100647377, COSV61937322; called by muse, mutect2, varscan2
- REXO1 | c.2439C>T p.V813= | Silent (SNP) | VAF 38/135 reads (28%) | catalogued as COSV50095341; called by muse, mutect2, varscan2
- SCN1A | c.5319C>T p.S1773= (on ENST00000303395 / NM_001202435.3; = p.S1762= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/212 reads (19%) | catalogued as COSV57689317; called by muse, mutect2, varscan2
- SEMG1 | c.570C>A p.S190= | Silent (SNP) | VAF 36/89 reads (40%) | catalogued as COSV54874758; called by muse, mutect2, varscan2
- SEZ6L2 | c.1869A>T p.P623= (on ENST00000308713 / NM_001114099.3; = p.P553= on NM_012410.4) | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV58104762; called by muse, mutect2, varscan2
- SIGLEC7 | c.531G>T p.G177= | Silent (SNP) | VAF 37/197 reads (19%) | catalogued as COSV58318052; called by muse, mutect2, varscan2
- SIPA1L3 | c.2550C>G p.T850= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV55925156; called by muse, mutect2, varscan2
- SLC25A17 | c.66A>T p.T22= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs754004021, COSV54353271; called by muse, mutect2, varscan2
- SLC35G3 | c.402C>T p.R134= | Silent (SNP) | VAF 67/215 reads (31%) | catalogued as COSV52012888; called by muse, mutect2, varscan2
- ST3GAL1 | c.369G>T p.V123= | Silent (SNP) | VAF 32/134 reads (24%) | catalogued as COSV60617042; called by muse, mutect2, varscan2
- STMN3 | c.60C>A p.L20= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV64247164; called by muse, mutect2, varscan2
- TAS1R1 | c.1068C>T p.S356= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV59840917; called by muse, mutect2, varscan2
- THBS2 | c.21G>A p.L7= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs1427152759, COSV64682433; called by muse, mutect2, varscan2
- TLR4 | c.144C>A p.I48= (on ENST00000355622 / NM_138554.5; = p.I8= on NM_003266.4) | Silent (SNP) | VAF 37/140 reads (26%) | catalogued as COSV62924359; called by muse, mutect2, varscan2
- TMC5 | c.63G>C p.G21= | Silent (SNP) | VAF 18/133 reads (14%) | catalogued as COSV66869161; called by muse, mutect2, varscan2
- TRBJ2-1 | c.52G>A p.*18= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as rs782774230; called by muse, mutect2
- TRMT1L | c.1713T>G p.P571= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV62273605; called by muse, mutect2, varscan2
- UBR1 | c.3960G>T p.L1320= | Silent (SNP) | VAF 44/159 reads (28%) | catalogued as COSV51937009; called by muse, mutect2, varscan2
- UNC5C | c.1326C>A p.L442= | Silent (SNP) | VAF 54/252 reads (21%) | catalogued as COSV71662546; called by muse, mutect2, varscan2
- USF2 | c.516G>T p.A172= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as COSV55888437; called by muse, mutect2, varscan2
- USF3 | c.1593A>G p.Q531= | Silent (SNP) | VAF 29/143 reads (20%) | catalogued as rs1401679305, COSV57077819; called by muse, mutect2, varscan2
- USP24 | c.1458A>T p.S486= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV53779564; called by muse, mutect2, varscan2
- ZP2 | c.834A>G p.P278= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as COSV54817126; called by muse, mutect2, varscan2
- COL6A5 | c.*81A>T | 3'UTR (SNP) | VAF 10/40 reads (25%) | catalogued as COSV55217489; called by muse, mutect2, varscan2
- FOLH1B | n.2132C>A | RNA (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2, varscan2
- PRR12 | c.52-452A>G | Intron (SNP) | VAF 6/27 reads (22%) | catalogued as COSV69820385; called by muse, mutect2, varscan2
- SMIM12 | chr1:34855223 C>A | 3'Flank (SNP) | VAF 13/96 reads (14%) | catalogued as COSV69904939; called by muse, mutect2, varscan2
- SNORD116-5 | n.56G>T | RNA (SNP) | VAF 27/139 reads (19%) | called by muse, mutect2, varscan2
- SSPOP | n.4279G>T | RNA (SNP) | VAF 8/47 reads (17%) | catalogued as rs767779542, COSV50489499; called by muse, mutect2, varscan2
- SSPOP | n.5679G>A | RNA (SNP) | VAF 3/18 reads (17%) | catalogued as rs1209061492, COSV50489504; called by muse, mutect2
- TMEM236 | c.*2166G>T | 3'UTR (SNP) | VAF 20/62 reads (32%) | catalogued as COSV100592567; called by muse, varscan2
- ZNF609 | c.-1G>T | 5'UTR (SNP) | VAF 11/81 reads (14%) | catalogued as COSV100440546; called by muse, mutect2, varscan2
- ZNF99 | c.*261A>G | 3'UTR (SNP) | VAF 35/189 reads (19%) | catalogued as rs1360477202, COSV68057031; called by muse, mutect2, varscan2
